Somatic mutation profile of tumor specimen ALCH-ADWO-TTP1-A (aliquot ALCH-ADWO-TTP1-A-1-0-D-A549-36) from ALCHEMIST case ALCH-ADWO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.6 years (24,338 days).
Specimen ALCH-ADWO-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8db05e6d-9d55-442e-84e2-a4fea6533e15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADWO-NB1-A (Blood Derived Normal), aliquot ALCH-ADWO-NB1-A-1-0-D-A549-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfb0dd60-06f5-403d-8a1e-918fd3fb280b

The open-access MAF lists 152 somatic variants for this specimen: 109 protein-altering or splice-affecting, 25 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 25, Intron 10, RNA 4, Frame Shift Ins 3, 3'UTR 2, Splice Site 2, 5'Flank 2, In Frame Del 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 136/396 reads (34%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by pindel, varscan2
- KEAP1 | c.1408C>A p.R470S | Missense Mutation (SNP) | VAF 198/380 reads (52%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV50260643, COSV50262012; called by muse, mutect2, varscan2
- RIT1 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 101/333 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs869025191, CM149836, CM161971, CM161972, COSV64170884, COSV64171290, COSV64171744; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.1737G>T p.Q579H | Missense Mutation (SNP) | VAF 158/379 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1440456943, COSV52232760; called by muse, mutect2, varscan2
- ADRA1B | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV60700574; called by muse, mutect2, varscan2
- ADRA2C | c.487C>A p.R163S | Missense Mutation (SNP) | VAF 55/239 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57468349; called by muse, mutect2, varscan2
- AMMECR1 | c.47C>G p.S16W | Missense Mutation (SNP) | VAF 111/170 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as rs766154270; called by muse, mutect2, varscan2
- AXIN2 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 533/879 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1060502159; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BICC1 | c.2587G>A p.G863R | Missense Mutation (SNP) | VAF 171/396 reads (43%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.973); catalogued as COSV99570018; called by muse, mutect2, varscan2
- CDH10 | c.1493G>C p.C498S | Missense Mutation (SNP) | VAF 40/468 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52594597; called by muse, mutect2
- CHGA | c.807G>C p.E269D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV53664815; called by muse, mutect2, varscan2
- CNOT1 | c.6133C>T p.R2045W | Missense Mutation (SNP) | VAF 50/368 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55316550; called by muse, mutect2, varscan2
- CRISPLD1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); catalogued as COSV100081531; called by muse, mutect2, varscan2
- ESPL1 | c.3583G>A p.A1195T | Missense Mutation (SNP) | VAF 47/722 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200640004, COSV57758575; called by muse, mutect2
- FRG2C | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 153/1383 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.971); catalogued as rs79506752, COSV57311821; called by muse, mutect2, varscan2
- FSTL4 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 108/197 reads (55%) | SIFT tolerated (0.95); PolyPhen benign (0.036); catalogued as COSV99532077; called by muse, mutect2, varscan2
- GALNT16 | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.178); catalogued as rs1011036663; called by muse, mutect2, varscan2
- GFRAL | c.550C>A p.Q184K | Missense Mutation (SNP) | VAF 84/439 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV61233098; called by muse, mutect2, varscan2
- HOXB3 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs747137585; called by muse, mutect2, varscan2
- HPS4 | c.359A>G p.N120S | Missense Mutation (SNP) | VAF 336/1093 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as rs1422848382; called by muse, mutect2, varscan2
- KIR2DL3 | c.226C>A p.H76N | Missense Mutation (SNP) | VAF 303/1014 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs1243685413; called by muse, mutect2, varscan2
- LIFR | c.2339G>T p.R780L | Missense Mutation (SNP) | VAF 206/532 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as COSV54691079; called by muse, mutect2
- LRRC37A3 | c.4727A>C p.Y1576S | Missense Mutation (SNP) | VAF 79/530 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs202058683; called by muse, mutect2, varscan2
- MKRN3 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 93/401 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs1461939355, COSV58808468, COSV58808530; called by muse, mutect2, varscan2
- NSD2 | c.3143C>T p.A1048V | Missense Mutation (SNP) | VAF 369/898 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs745664737, COSV56387439; called by muse, mutect2, varscan2
- P2RX7 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 197/1199 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs200779736; called by muse, mutect2, varscan2
- PLXNA4 | c.3509C>T p.P1170L | Missense Mutation (SNP) | VAF 79/264 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs746921698, COSV58121834; called by muse, mutect2, varscan2
- PNPLA3 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 93/1124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53379086; called by muse, mutect2
- PPWD1 | c.1255A>G p.I419V | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200778132; called by muse, mutect2, varscan2
- PXDNL | c.2342G>C p.R781P | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781570739, COSV62487783; called by muse, mutect2, varscan2
- SART1 | c.2353G>A p.V785M | Missense Mutation (SNP) | VAF 346/486 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1173465858; called by muse, mutect2, varscan2
- SERPINB11 | c.208G>T p.G70W | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV101236323; called by muse, varscan2
- SNRPN | c.134G>T p.C45F | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57597714; called by muse, mutect2
- SNX27 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.095); catalogued as rs1181173678; called by mutect2, varscan2
- TTN | c.101840T>C p.I33947T (on ENST00000591111; = p.I26523T on NM_003319.4) | Missense Mutation (SNP) | VAF 154/603 reads (26%) | PolyPhen benign (0.022); catalogued as rs777089547; called by muse, mutect2, varscan2
- TUBA3D | c.782C>A p.P261Q | Missense Mutation (SNP) | VAF 159/388 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV58312215; called by muse, mutect2, varscan2
- UGT3A1 | c.362G>A p.C121Y | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476702678; called by muse, mutect2, varscan2
- VPS13D | c.6507G>C p.E2169D | Missense Mutation (SNP) | VAF 194/726 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1426318034; called by muse, varscan2
- XKR4 | c.712C>G p.R238G | Missense Mutation (SNP) | VAF 134/307 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV59319805; called by muse, mutect2, varscan2
- ZNF213 | c.522C>T p.S174= | Splice Region (SNP) | VAF 66/483 reads (14%) | catalogued as rs140652197; called by muse, mutect2, varscan2
- ZNF93 | c.915A>C p.K305N | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.543); catalogued as rs1185933475; called by muse, mutect2, varscan2
- ABCC2 | c.262A>G p.T88A | Missense Mutation (SNP) | VAF 88/535 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.10754C>A p.T3585K | Missense Mutation (SNP) | VAF 120/658 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATMIN | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 104/191 reads (54%) | called by muse, mutect2, varscan2
- CCER1 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CDH23 | c.6101C>T p.P2034L | Missense Mutation (SNP) | VAF 99/409 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CIPC | c.123C>A p.D41E | Missense Mutation (SNP) | VAF 111/247 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRTAP | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 94/244 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- DGKB | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 105/267 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- DIDO1 | c.510G>T p.R170S | Missense Mutation (SNP) | VAF 126/756 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- DMBT1 | c.6148G>A p.E2050K (on ENST00000338354 / NM_001377530.1; = p.E1293K on NM_004406.3) | Missense Mutation (SNP) | VAF 182/460 reads (40%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- DOCK4 | c.3108-1G>T p.X1036_splice | Splice Site (SNP) | VAF 51/310 reads (16%) | called by muse, mutect2, varscan2
- ECE1 | c.115dup p.D39Gfs*86 | Frame Shift Ins (INS) | VAF 38/93 reads (41%) | called by mutect2, pindel, varscan2
- EP300 | c.4408dup p.M1470Nfs*3 | Frame Shift Ins (INS) | VAF 206/642 reads (32%) | called by mutect2, varscan2
- EPHA8 | c.759G>T p.W253C | Missense Mutation (SNP) | VAF 66/116 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM90A1 | c.340A>T p.R114W | Missense Mutation (SNP) | VAF 627/1193 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FCRL4 | c.1514C>T p.A505V | Missense Mutation (SNP) | VAF 153/612 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSCN2 | c.1411_1442del p.G471Rfs*23 | Frame Shift Del (DEL) | VAF 48/398 reads (12%) | called by mutect2, pindel
- GABBR2 | c.1894C>A p.P632T | Missense Mutation (SNP) | VAF 177/271 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- GOLT1B | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GRM4 | c.130C>A p.R44S | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- HIGD1A | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 70/202 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- IGHV1-24 | c.179C>A p.P60H | Missense Mutation (SNP) | VAF 229/1003 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- IGHV1-24 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 225/998 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- IL12RB1 | c.1867T>A p.W623R | Missense Mutation (SNP) | VAF 138/246 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, varscan2
- IMPG1 | c.573C>A p.N191K | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITPRIPL1 | c.175T>A p.F59I (on ENST00000439118 / NM_001008949.3; = p.F67I on NM_178495.6) | Missense Mutation (SNP) | VAF 314/756 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KLRC1 | c.502A>T p.I168F | Missense Mutation (SNP) | VAF 308/551 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- KRT75 | c.1570A>T p.T524S | Missense Mutation (SNP) | VAF 215/1257 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRFN2 | c.497G>T p.W166L | Missense Mutation (SNP) | VAF 96/492 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRIG3 | c.1892C>G p.A631G | Missense Mutation (SNP) | VAF 25/404 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.266); called by muse, mutect2
- LTBP3 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 422/572 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LYL1 | c.611G>C p.R204P | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- MAP3K4 | c.4600G>T p.V1534F | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP7D3 | c.2561C>A p.S854Y | Missense Mutation (SNP) | VAF 267/363 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- MDC1 | c.4472C>A p.P1491H | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- MMUT | c.755A>G p.H252R | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); called by muse, varscan2
- MROH2B | c.3035T>C p.M1012T | Missense Mutation (SNP) | VAF 76/296 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYOF | c.2050G>T p.A684S | Missense Mutation (SNP) | VAF 71/518 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAV2 | c.5960A>G p.H1987R (on ENST00000396087 / NM_001244963.2; = p.H1928R on NM_145117.5) | Missense Mutation (SNP) | VAF 193/295 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- NEB | c.5797_5799del p.K1933del | In Frame Del (DEL) | VAF 32/201 reads (16%) | called by mutect2, pindel, varscan2
- NPHS1 | c.609-1G>T p.X203_splice | Splice Site (SNP) | VAF 227/391 reads (58%) | called by muse, mutect2, varscan2
- OR51B5 | c.463G>T p.V155F | Missense Mutation (SNP) | VAF 226/302 reads (75%) | SIFT tolerated (0.56); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PDE8A | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- PIEZO2 | c.4271T>A p.L1424Q | Missense Mutation (SNP) | VAF 135/225 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIK3C2G | c.1715A>C p.K572T | Missense Mutation (SNP) | VAF 32/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRAMEF19 | c.330G>C p.E110D | Missense Mutation (SNP) | VAF 76/1356 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2
- PRDM9 | c.1429T>C p.S477P | Missense Mutation (SNP) | VAF 86/1034 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2
- PRG4 | c.1976C>A p.T659N | Missense Mutation (SNP) | VAF 128/307 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- RGS14 | c.886A>C p.S296R | Missense Mutation (SNP) | VAF 187/318 reads (59%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RIDA | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 167/695 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RPL5 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.094); called by muse, mutect2
- RPTN | c.1811C>G p.T604R | Missense Mutation (SNP) | VAF 448/1509 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- SIPA1L1 | c.5281G>C p.D1761H | Missense Mutation (SNP) | VAF 94/204 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMURF1 | c.1887G>T p.E629D | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SNRPN | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SP8 | c.1309A>T p.T437S (on ENST00000361443 / NM_198956.4; = p.T455S on NM_182700.6) | Missense Mutation (SNP) | VAF 90/559 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- SP8 | c.1308G>T p.K436N (on ENST00000361443 / NM_198956.4; = p.K454N on NM_182700.6) | Missense Mutation (SNP) | VAF 90/565 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- STAB2 | c.1652G>T p.G551V | Missense Mutation (SNP) | VAF 59/384 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- STAC | c.964T>A p.W322R | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- SVEP1 | c.3803A>C p.E1268A | Missense Mutation (SNP) | VAF 109/173 reads (63%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM209 | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 40/686 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.383); called by muse, mutect2
- TRIM65 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 26/831 reads (3%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.506); called by muse, mutect2
- TTC38 | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 118/378 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY3 | c.7529C>G p.A2510G | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZFHX4 | c.4903G>T p.G1635W | Missense Mutation (SNP) | VAF 150/307 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF496 | c.478A>G p.S160G | Missense Mutation (SNP) | VAF 30/344 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- ZNF83 | c.198C>A p.H66Q | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ZNF888 | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 51/488 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, varscan2
- ALKBH1 | c.501A>G p.K167= | Silent (SNP) | VAF 216/653 reads (33%) | called by muse, mutect2, varscan2
- ARHGAP9 | c.1678C>A p.R560= (on ENST00000393797 / NM_001319850.2; = p.R541= on NM_032496.4) | Silent (SNP) | VAF 106/785 reads (14%) | catalogued as COSV99953543; called by muse, mutect2, varscan2
- BARD1 | c.2241A>T p.P747= | Silent (SNP) | VAF 183/455 reads (40%) | called by muse, mutect2, varscan2
- DENND3 | c.258G>A p.L86= | Silent (SNP) | VAF 70/251 reads (28%) | called by muse, mutect2, varscan2
- GPT2 | c.1173C>T p.P391= | Silent (SNP) | VAF 106/364 reads (29%) | catalogued as rs1045090373; called by muse, mutect2, varscan2
- GRID2 | c.1620C>T p.Y540= | Silent (SNP) | VAF 175/370 reads (47%) | called by muse, mutect2, varscan2
- HECTD4 | c.5400G>A p.A1800= | Silent (SNP) | VAF 59/499 reads (12%) | catalogued as rs371288014, COSV101107855; called by muse, mutect2, varscan2
- HP1BP3 | c.582G>A p.L194= | Silent (SNP) | VAF 52/227 reads (23%) | called by muse, mutect2, varscan2
- ITIH1 | c.2367G>T p.V789= | Silent (SNP) | VAF 37/477 reads (8%) | called by muse, mutect2
- KMT2C | c.13086T>C p.I4362= | Silent (SNP) | VAF 52/399 reads (13%) | called by muse, mutect2, varscan2
- MPHOSPH10 | c.570A>T p.G190= | Silent (SNP) | VAF 103/376 reads (27%) | called by muse, mutect2, varscan2
- MROH1 | c.2811G>A p.A937= | Silent (SNP) | VAF 144/1050 reads (14%) | catalogued as rs1431389570; called by muse, mutect2, varscan2
- MYF6 | c.192G>C p.A64= | Silent (SNP) | VAF 345/724 reads (48%) | catalogued as COSV57350855; called by muse, mutect2, varscan2
- NHLRC1 | c.513C>T p.A171= | Silent (SNP) | VAF 90/247 reads (36%) | catalogued as rs148907696; ClinVar: benign / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- POU3F4 | c.858G>A p.E286= | Silent (SNP) | VAF 30/124 reads (24%) | called by muse, mutect2, varscan2
- PRRT4 | c.2697G>T p.L899= | Silent (SNP) | VAF 125/293 reads (43%) | called by muse, mutect2, varscan2
- PRSS1 | c.240C>G p.V80= | Silent (SNP) | VAF 134/1134 reads (12%) | catalogued as COSV61191008; called by muse, varscan2
- PSMD1 | c.834G>A p.V278= | Silent (SNP) | VAF 95/587 reads (16%) | called by muse, mutect2, varscan2
- RBL1 | c.1047T>A p.A349= | Silent (SNP) | VAF 76/200 reads (38%) | called by muse, mutect2, varscan2
- SPAG16 | c.1674C>T p.I558= | Silent (SNP) | VAF 108/304 reads (36%) | catalogued as rs376387182; called by muse, mutect2, varscan2
- TET1 | c.675A>G p.E225= | Silent (SNP) | VAF 143/316 reads (45%) | catalogued as rs768429010; called by muse, mutect2, varscan2
- TMPRSS9 | c.2853G>A p.A951= (on ENST00000648592; = p.A917= on NM_182973.2) | Silent (SNP) | VAF 85/344 reads (25%) | catalogued as COSV53113439; called by muse, mutect2, varscan2
- VAX2 | c.310C>A p.R104= | Silent (SNP) | VAF 60/181 reads (33%) | called by muse, mutect2, varscan2
- ZIM3 | c.846T>C p.N282= | Silent (SNP) | VAF 134/206 reads (65%) | catalogued as rs370677957; called by muse, mutect2, varscan2
- ZNF730 | c.120G>T p.L40= | Silent (SNP) | VAF 77/206 reads (37%) | called by muse, mutect2, varscan2
- AC068587.7 | chr8:12659463 G>C | 5'Flank (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- AGAP12P | n.1311C>A | RNA (SNP) | VAF 46/351 reads (13%) | called by mutect2, varscan2
- CCDC40 | c.2832+482G>C | Intron (SNP) | VAF 410/711 reads (58%) | called by muse, mutect2, varscan2
- CNTROB | c.2513+61G>A | Intron (SNP) | VAF 78/356 reads (22%) | called by muse, mutect2, varscan2
- CST9LP1 | n.417C>A | RNA (SNP) | VAF 56/365 reads (15%) | catalogued as rs1028611032; called by muse, mutect2, varscan2
- DCAF17 | c.*1767_*1776del | 3'UTR (DEL) | VAF 74/224 reads (33%) | called by mutect2, pindel, varscan2
- DLG2 | c.205-65642G>T | Intron (SNP) | VAF 375/561 reads (67%) | catalogued as COSV99720318; called by muse, mutect2, varscan2
- GALNT9 | c.1077+346G>A | Intron (SNP) | VAF 38/235 reads (16%) | called by muse, mutect2, varscan2
- LINC01949 | n.1256C>A | RNA (SNP) | VAF 25/32 reads (78%) | called by muse, mutect2, varscan2
- LTBP3 | c.2597-44G>A | Intron (SNP) | VAF 34/476 reads (7%) | catalogued as rs748024506; called by muse, mutect2
- NDUFAF5 | c.*876G>C | 3'UTR (SNP) | VAF 59/315 reads (19%) | called by muse, mutect2, varscan2
- PDCD6IP | c.835-733T>A | Intron (SNP) | VAF 107/308 reads (35%) | called by muse, mutect2, varscan2
- PROM2 | c.295-34T>G | Intron (SNP) | VAF 56/190 reads (29%) | called by muse, varscan2
- RARG | c.1018+64A>G | Intron (SNP) | VAF 136/284 reads (48%) | called by muse, mutect2, varscan2
- RNU6-316P | chr18:14187241 G>A | 5'Flank (SNP) | VAF 120/205 reads (59%) | called by muse, mutect2, varscan2
- SMPD4 | c.1215-132G>T | Intron (SNP) | VAF 141/321 reads (44%) | called by muse, mutect2, varscan2
- SSX6P | n.261C>A | RNA (SNP) | VAF 269/359 reads (75%) | called by muse, mutect2, varscan2
- STIM2 | c.1764-997A>T | Intron (SNP) | VAF 139/526 reads (26%) | called by muse, mutect2, varscan2
